Somatic mutation profile of tumor specimen TCGA-DS-A3LQ-01A (aliquot TCGA-DS-A3LQ-01A-21D-A21Q-09) from TCGA case TCGA-DS-A3LQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 46.2 years (16,861 days).
Specimen TCGA-DS-A3LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec23155c-e0b1-4587-98da-9e01b8e238ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A3LQ-10A (Blood Derived Normal), aliquot TCGA-DS-A3LQ-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26c321f9-139d-45fb-8aae-edaaaee14fd5

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 74/111 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960000, COSV67960068, COSV67960466; called by muse, varscan2
- ADGRV1 | c.18548C>T p.T6183M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201790936; called by muse, mutect2, varscan2
- ASNSD1 | c.1054_1056del p.L352del | In Frame Del (DEL) | VAF 17/23 reads (74%) | catalogued as rs758018468; called by pindel, varscan2
- CHST15 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100655381; called by muse, mutect2, varscan2
- CREBBP | c.4804C>T p.R1602C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1313429, COSV52125055; called by muse, mutect2
- DLG1 | c.636+1G>A p.X212_splice | Splice Site (SNP) | VAF 98/135 reads (73%) | catalogued as rs1210809636, COSV58378046; called by muse, mutect2, varscan2
- DNAH11 | c.6232G>A p.G2078R | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776879195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HUNK | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs190270753, COSV54225455; called by muse, mutect2, varscan2
- NPIPB7 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as rs201682937, COSV71745148; called by muse, mutect2, varscan2
- SLAMF6 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1385121818; called by muse, mutect2, varscan2
- STC1 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV51688960, COSV99282748; called by muse, mutect2, varscan2
- ZNF45 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs765816598; called by muse, mutect2, varscan2
- ZNF648 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV60569693; called by muse, mutect2, varscan2
- AHNAK | c.15199C>T p.P5067S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- ATP13A5 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- BRINP3 | c.618+1G>A p.X206_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- BTBD1 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR2G3 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PBDC1 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAD51AP1 | c.938G>A p.S313N (on ENST00000228843 / NM_001130862.2; = p.S296N on NM_006479.5) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RARG | c.1186A>G p.R396G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- RUNX2 | c.959dup p.L321Afs*17 | Frame Shift Ins (INS) | VAF 21/42 reads (50%) | called by mutect2, pindel, varscan2
- SPHKAP | c.2172G>A p.M724I | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIP10 | c.1613C>T p.P538L (on ENST00000313244 / NM_001288962.2; = p.P482L on NM_004240.4) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TSC2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 63/90 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TXNIP | c.705_708del p.V237Efs*40 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | called by mutect2, pindel, varscan2
- AMOT | c.2682C>T p.A894= (on ENST00000371959 / NM_001113490.1; = p.A485= on NM_133265.3) | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1213538901, COSV100495598; called by muse, mutect2, varscan2
- ATG2A | c.1578G>A p.L526= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV101034856; called by muse, mutect2
- BRD3 | c.990C>T p.Y330= | Silent (SNP) | VAF 75/91 reads (82%) | catalogued as rs372612317; called by muse, mutect2, varscan2
- BRINP1 | c.255C>T p.I85= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs758282699, COSV99774176; called by muse, mutect2, varscan2
- CILP2 | c.1593C>T p.F531= | Silent (SNP) | VAF 29/107 reads (27%) | called by muse, mutect2, varscan2
- HERC2 | c.7980T>A p.S2660= | Silent (SNP) | VAF 41/161 reads (25%) | called by muse, mutect2, varscan2
- IL6ST | c.411C>T p.N137= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs774387992; called by muse, mutect2, varscan2
- KIF1A | c.2331G>A p.T777= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1177964009; called by muse, mutect2, varscan2
- TPO | c.1731C>T p.S577= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- MIR520D | n.70G>A | RNA (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- RNF5 | c.*2C>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | catalogued as rs1475160933, COSV100426293; called by muse, mutect2, varscan2
- SND1 | c.1779+6783G>A | Intron (SNP) | VAF 35/96 reads (36%) | catalogued as rs752834511, COSV100690353; called by muse, mutect2, varscan2
